Surgical pathology report (de-identified scan), TCGA case TCGA-D7-6818, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-6818-01A (Primary Tumor).

Examination: **Histopathological examination**

Internal invoice No.

Cost of diagnostic procedure

Examination No.: [REDACTED]

Patient: **XXX**PESEL: **XXX**

Age: [REDACTED]

Gender: [REDACTED]

Material: **Multiple organ resection – stomach**

Unit in charge: [REDACTED]

Physician in charge: [REDACTED]

Material collected on: [REDACTED] **1** Material received on: [REDACTED]

Expected time of examination: [REDACTED]

Clinical diagnosis: **Bleeding gastric cancer.** **Gastric cancer**

Examination performed on: [REDACTED]Macroscopic description:

The collected material consisting of a the stomach, after being incised along the greater curvature sized 23.3 x 15.3 cm with the omentum sized 10.4 x 15 cm. Tumour sized 6.8 x 6.4 x 0,3 cm found on the lesser curvature. Distance from the proximal end 2.3 cm, from distal end, 5.2 cm.

Microscopic description:

Adenocarcinoma mucocellulare et unfifferentiatum ventriculi (G3, typ rozlany): infiltratio telae adiposae (pT2).

Neoplastic infiltration present in the proximal incision line.

Distal line and omentum – no neoplastic lesions found.

Lymph nodes – metastases in lymphonodis (X / XXI) (pN3).

Histopathological diagnosis:

Adenocarcinoma mucocellulare et udifferentiatum ventriculi. Mucocellular and undifferentiated adenocarcinoma of the stomach.

Metastases in lymphonodis. Cancer metastases in the lymph nodes (XI / XXII).

(G3, pT2, pN3)..

Compliance validated by: [REDACTED]

Source: NCI Genomic Data Commons file a09f7b2e-d329-4314-aae2-6aebab23b95b (TCGA-D7-6818.EF03AA87-1B7F-440D-B9EA-AC3D4FA03ED8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).